Somatic mutation profile of tumor specimen TCGA-MQ-A6BS-01A (aliquot TCGA-MQ-A6BS-01A-12D-A34C-32) from TCGA case TCGA-MQ-A6BS, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 55.8 years (20,384 days).
Specimen TCGA-MQ-A6BS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eff7874-768c-4c49-bdc5-cd387f96e9dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A6BS-10A (Blood Derived Normal), aliquot TCGA-MQ-A6BS-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98f4f13b-72ef-4b44-a50c-0e81d8629f56

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, Translation Start Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC004832.3 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369159462; called by muse, mutect2, varscan2
- CHRM5 | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 55/218 reads (25%) | catalogued as rs1328896835; called by muse, mutect2, varscan2
- CIRBP | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.972); catalogued as rs747328699; called by muse, mutect2, varscan2
- COMMD8 | c.179A>G p.K60R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV67500335; called by muse, mutect2
- CTCF | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99865833; called by muse, mutect2, varscan2
- FLOT1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs761767550, COSV52544574; called by muse, mutect2, varscan2
- KCNE5 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV100927704; called by muse, mutect2, varscan2
- LRP1 | c.7945C>T p.R2649C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1243980327; called by muse, mutect2
- MAP2K3 | c.545G>C p.S182T (on ENST00000342679 / NM_145109.3; = p.S153T on NM_002756.4) | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.525); catalogued as COSV57578877; called by muse, mutect2, varscan2
- PKP3 | c.2073G>C p.E691D | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV58986390; called by muse, mutect2, varscan2
- RELN | c.2842G>A p.V948M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100634790; called by muse, mutect2, varscan2
- TTN | c.15320C>T p.A5107V (on ENST00000591111; = p.A4180V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/193 reads (39%) | PolyPhen benign (0.104); catalogued as rs1466084495, COSV100619494; called by muse, mutect2, varscan2
- ZNF226 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs769401601; called by muse, mutect2, varscan2
- AVPR2 | c.970A>T p.I324F | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CARD6 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASC3 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- CCP110 | c.2207C>G p.T736S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DUSP22 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 117/253 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FAT1 | c.11844C>G p.N3948K | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.403); called by muse, mutect2
- FRMD6 | c.100G>T p.V34F | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GK5 | c.772G>C p.V258L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LSP1 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGI3 | c.1809G>C p.M603I | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MAU2 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NCSTN | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RHOXF1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SETD2 | c.5257dup p.T1753Nfs*36 | Frame Shift Ins (INS) | VAF 67/122 reads (55%) | called by mutect2, pindel, varscan2
- TAPBP | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- TTC14 | c.2119_2135del p.T707* | Frame Shift Del (DEL) | VAF 21/115 reads (18%) | called by mutect2, pindel, varscan2
- VPS54 | c.2632G>A p.V878M | Missense Mutation (SNP) | VAF 60/93 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EFHB | c.1590T>C p.H530= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs1307911705; called by muse, mutect2, varscan2
- KRT12 | c.1170C>A p.L390= | Silent (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- MERTK | c.2442C>A p.L814= | Silent (SNP) | VAF 32/174 reads (18%) | called by muse, mutect2, varscan2
- MYH1 | c.2130G>A p.R710= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs1204245669, COSV99876064; called by muse, mutect2, varscan2
- OPRM1 | c.105C>T p.S35= | Silent (SNP) | VAF 47/62 reads (76%) | called by muse, mutect2, varscan2
- PTPRB | c.540T>C p.N180= | Silent (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- SALL3 | c.1845G>A p.A615= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs774733461; called by muse, mutect2, varscan2
- SIGLEC11 | c.1974G>A p.A658= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs367661039; called by muse, mutect2, varscan2
- SPTLC1 | c.675G>A p.E225= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV52764957; called by muse, mutect2, varscan2
- UBN1 | c.2430C>T p.G810= | Silent (SNP) | VAF 53/190 reads (28%) | called by muse, mutect2, varscan2
- ZNF26 | c.726G>A p.R242= | Silent (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- NCAPD2 | c.262+161G>C | Intron (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- SNORD116-8 | n.77C>T | RNA (SNP) | VAF 47/131 reads (36%) | called by muse, mutect2, varscan2
